Gene-level copy-number profile of tumor specimen C3N-02785-01 from CPTAC case C3N-02785, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.3 years (25,301 days).
Specimen C3N-02785-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7450caf8-c8f6-44d9-aceb-3a4d96648c40.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02785-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/37c145d1-bb24-48dd-a6da-33e470e8a993

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 6; copy number 2: 3,018; copy number 3: 39; copy number 4: 38,153; copy number 5: 4,229; copy number 6: 10,461; copy number 7: 31; copy number 8: 2,867; copy number 9: 1; copy number 11: 1; copy number 70: 26; copy number 215: 12.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–4): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:21,174,014–21,372,950, 5 genes (within-gene range 0–4): NEBL-AS1, AL731547.1, LUZP4P1, RNU6-15P, LINC02643.
- chr10:21,756,548–22,003,769, 4 genes (within-gene range 0–4): DNAJC1, RN7SKP219, AL359697.1, RN7SKP37.
- chr10:23,694,746–26,212,532, 27 genes (within-gene range 0–4): KIAA1217, NUP35P1, AC063961.1, MIR603, AL356113.1, AL353583.1, ARHGAP21, RNA5SP305, PRTFDC1, AL157385.1, RN7SKP241, AL512598.2, AL512598.1, ENKUR, THNSL1, LINC01516, GPR158-AS1, GPR158, AL354976.1, RN7SKP220, GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P, AL358612.1, MYO3A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 40 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,064,533–204,728,106, 26 genes, copy number 70: AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr7:54,556,970–55,260,256, 12 genes, copy number 215 (within-gene range 8–215): VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr9:61,642,383–61,642,494, 1 gene, copy number 9: Y_RNA.
- chr15:90,352,284–90,369,146, 1 gene, copy number 11: ZNF774.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
